Somatic mutation profile of tumor specimen BA2275D (aliquot aq-BA2275D) from BEATAML1.0 case 2199, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 57.8 years (21,094 days).
Specimen BA2275D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 99021232-c57a-4963-bef6-8a619e1a2767.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2736D (Solid Tissue Normal), aliquot aq-BA2736D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b16f05e8-f9d6-4b90-9af2-6ea42b257174

The open-access MAF lists 16 somatic variants for this specimen: 11 protein-altering or splice-affecting, 1 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Intron 2, 5'UTR 1, 3'Flank 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CNTNAP3 | c.2647A>G p.R883G | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1480487119; called by muse, mutect2, varscan2
- EYS | c.6601C>G p.L2201V | Missense Mutation (SNP) | VAF 64/162 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); catalogued as COSV101010012; called by mutect2, varscan2
- FAM149A | c.1933C>T p.H645Y (on ENST00000356371 / NM_001367768.2; = p.H354Y on NM_015398.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 53/100 reads (53%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs762976282; called by muse, mutect2, varscan2
- FAT1 | c.844G>T p.D282Y | Missense Mutation (SNP) | VAF 35/68 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781077372, COSV71673661; called by muse, mutect2, varscan2
- GRIN2B | c.3647G>T p.R1216L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV74206475, COSV74207338; called by mutect2, varscan2
- LMAN1 | c.1285G>A p.V429I | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs370794143; called by muse, mutect2, varscan2
- C10orf82 | c.93G>T p.K31N | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2
- FBXO38 | c.1886C>A p.T629N | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); called by muse, mutect2
- GRPR | c.312C>A p.D104E | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.54); PolyPhen benign (0.1); called by muse, mutect2
- PCARE | c.2835G>T p.E945D | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.59); PolyPhen benign (0.009); called by muse, mutect2
- PGLYRP1 | c.274G>C p.D92H | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, varscan2
- PAN3 | c.2268A>G p.Q756= | Silent (SNP) | VAF 41/97 reads (42%) | catalogued as rs1280888034; called by muse, mutect2, varscan2
- ARFGAP2 | c.481-66G>A | Intron (SNP) | VAF 32/67 reads (48%) | catalogued as rs1025553223; called by muse, mutect2, varscan2
- CICP28 | chr7:56811981 A>C | 3'Flank (SNP) | VAF 10/76 reads (13%) | catalogued as rs781998069; called by muse, varscan2
- MAD1L1 | c.1999-22526C>T | Intron (SNP) | VAF 32/62 reads (52%) | catalogued as rs955231728; called by muse, mutect2
- TGFBR3 | c.-169G>T | 5'UTR (SNP) | VAF 3/32 reads (9%) | called by muse, mutect2
